Somatic mutation profile of tumor specimen 0DVJOK from CCDI case PBCMVV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Mesenchymal chondrosarcoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 10.7 years (3,909 days).
Specimen 0DVJOK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d50e782-ef3c-4537-83af-5f1b603631ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVJNU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30ec8c1b-7dd7-4747-943b-14090c8d9bc5

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR4K5 | c.233C>G p.T78S | Missense Mutation (SNP) | VAF 20/440 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2
- OR8U1 | c.310T>G p.F104V | Missense Mutation (SNP) | VAF 25/678 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCSK6 | c.2570G>A p.G857E | Missense Mutation (SNP) | VAF 170/426 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FTHL17 | c.231C>A p.R77= | Silent (SNP) | VAF 115/363 reads (32%) | catalogued as COSV100784463; called by muse, mutect2, varscan2
- KLHL28 | c.1287G>A p.A429= | Silent (SNP) | VAF 32/544 reads (6%) | catalogued as rs367703243; called by muse, mutect2
- CLEC4M | c.784+54T>A | Intron (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- CTSF | c.-55C>A | 5'UTR (SNP) | VAF 54/98 reads (55%) | called by muse, mutect2, varscan2
- SEMA4A | c.1134+61C>A | Intron (SNP) | VAF 76/185 reads (41%) | called by muse, mutect2, varscan2
